Somatic mutation profile of tumor specimen TARGET-30-PAPLSD-01A (aliquot TARGET-30-PAPLSD-01A-01D) from TARGET case TARGET-30-PAPLSD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.9 years (710 days).
Specimen TARGET-30-PAPLSD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8706bae7-4915-40b1-b4ec-bd7f0c29f44c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPLSD-10A (Blood Derived Normal), aliquot TARGET-30-PAPLSD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a7c1bf9-cccd-4351-8aea-41c56d9ab0b2

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 44/96 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC11 | c.1258A>G p.M420V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181307743, COSV62321591; called by muse, mutect2, varscan2
- ACSF2 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV51971524; called by muse, mutect2, varscan2
- AP002748.5 | c.872C>A p.S291Y | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV59147261; called by muse, mutect2, varscan2
- APOBR | c.2966C>G p.P989R (on ENST00000431282; = p.P998R on NM_018690.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100112433, COSV60489025; called by muse, mutect2
- C1S | c.2008A>G p.N670D | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV61070216; called by muse, mutect2, varscan2
- CA10 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 19/132 reads (14%) | catalogued as COSV53339803, COSV53373955; called by muse, mutect2
- CBX2 | c.1032G>C p.Q344H | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV53968549; called by muse, mutect2, varscan2
- COIL | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV53594042; called by muse, mutect2, varscan2
- CYP2C9 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs764766385, COSV53246937; called by muse, mutect2, varscan2
- HUWE1 | c.6139G>A p.E2047K | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV53336327; called by muse, mutect2, varscan2
- KRT25 | c.721A>G p.N241D | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.174); catalogued as COSV56443850; called by muse, mutect2, varscan2
- KRTAP9-9 | c.269G>T p.C90F | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); catalogued as rs796908797, COSV67453850; called by muse, mutect2, varscan2
- MIDEAS | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.049); catalogued as COSV54093106; called by muse, mutect2, varscan2
- MYLK2 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV65658640; called by muse, mutect2, varscan2
- MYO5B | c.2296A>T p.T766S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53212488; called by muse, mutect2, varscan2
- NSF | c.2123A>G p.K708R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751921136, COSV56573988; called by muse, mutect2, varscan2
- OFD1 | c.2692C>T p.Q898* | Nonsense Mutation (SNP) | VAF 68/79 reads (86%) | catalogued as COSV57421512; called by muse, mutect2, varscan2
- OR4C12 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV58859481; called by muse, mutect2, varscan2
- OR5B12 | c.657A>G p.I219M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56904128; called by muse, mutect2, varscan2
- PDZRN4 | c.2207C>T p.S736F (on ENST00000402685 / NM_001164595.2; = p.S478F on NM_013377.4) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868597327, COSV100115275, COSV54192745; called by muse, mutect2
- PLCD4 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68842097; called by muse, mutect2, varscan2
- PPP1R26 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV63354841; called by muse, mutect2, varscan2
- PREX1 | c.2594T>C p.V865A | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV64248397; called by muse, mutect2, varscan2
- TM4SF4 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59515239; called by muse, mutect2, varscan2
- TRRAP | c.5586G>C p.M1862I (on ENST00000359863 / NM_001244580.1; = p.M1844I on NM_003496.3) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV62840172; called by muse, mutect2, varscan2
- WNK4 | c.3077C>A p.A1026D | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1415938074, COSV55901826; called by muse, mutect2, varscan2
- IL3 | c.426T>A p.A142= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV57308528; called by muse, mutect2, varscan2
- INSR | c.3618G>A p.E1206= | Silent (SNP) | VAF 138/416 reads (33%) | catalogued as rs771839433, CM940985, COSV57158572; called by muse, mutect2, varscan2
- MAML2 | c.561C>A p.A187= | Silent (SNP) | VAF 48/70 reads (69%) | catalogued as COSV73262855; called by muse, mutect2, varscan2
- MYCBP2 | c.13530A>G p.R4510= (on ENST00000357337; = p.R4548= on NM_015057.5) | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as COSV62011502; called by muse, varscan2
- PCDHB14 | c.369C>A p.V123= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV53386793; called by muse, mutect2, varscan2
- PDHA2 | c.1065T>C p.P355= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV54777555; called by muse, mutect2, varscan2
- SIRT6 | c.15C>T p.Y5= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs200766576, COSV59446702; called by muse, mutect2, varscan2
- STXBP5L | c.640T>C p.L214= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV56502112, COSV99871830; called by muse, mutect2, varscan2
- SZT2 | c.117G>T p.L39= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV60289672; called by muse, mutect2, varscan2
